Somatic mutation profile of tumor specimen TCGA-A3-3372-01A (aliquot TCGA-A3-3372-01A-01W-0886-08) from TCGA case TCGA-A3-3372, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.4 years (23,528 days).
Specimen TCGA-A3-3372-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fac268f9-401a-445e-b81e-79830fa43535.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3372-11A (Solid Tissue Normal), aliquot TCGA-A3-3372-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da421d2d-4d28-4dbd-8108-e810e9d75db6

The open-access MAF lists 83 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 18, Frame Shift Del 6, Frame Shift Ins 5, Nonsense Mutation 4, Splice Site 3, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- BMPR2 | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 49/305 reads (16%) | catalogued as rs137852748, CM002242, COSV65808086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM1 | c.1987G>T p.G663W | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278874999, COSV53302573; called by muse, mutect2, varscan2
- ANO6 | c.2159A>G p.D720G | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs758909661, COSV57658745; called by muse, mutect2, varscan2
- ATP12A | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); catalogued as COSV54513953; called by muse, mutect2, varscan2
- BECN1 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1423754164, COSV64120654; called by muse, mutect2, varscan2
- BTBD7 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV54134619; called by muse, mutect2
- BTN1A1 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV55067016; called by muse, mutect2, varscan2
- CMYA5 | c.7153C>T p.P2385S | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); catalogued as rs1330329088, COSV71404673; called by muse, mutect2, varscan2
- CPNE7 | c.1380C>A p.D460E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV52011625; called by muse, mutect2
- CYP8B1 | c.1340T>A p.L447H | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1384425084, COSV60225899; called by muse, mutect2, varscan2
- DNAH9 | c.6517C>T p.R2173W | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs774222974, COSV52340595; called by muse, mutect2, varscan2
- DTNA | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1487728774, COSV51995645; called by muse, mutect2, varscan2
- EDA | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65780359; called by muse, mutect2, varscan2
- FAM120AOS | c.727A>C p.T243P | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV52902878; called by muse, mutect2
- FASTKD1 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV70006709; called by muse, mutect2, varscan2
- GABBR1 | c.2347C>A p.L783M | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV63541633; called by muse, mutect2, varscan2
- GPM6A | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 79/393 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1271491889, COSV54536347; called by muse, mutect2, varscan2
- GRIK3 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV66137195; called by muse, mutect2, varscan2
- HECTD1 | c.7067G>A p.R2356K | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); catalogued as COSV67945576; called by muse, mutect2, varscan2
- KIF16B | c.112T>G p.L38V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV61703335; called by muse, mutect2, varscan2
- LRFN5 | c.197T>G p.I66S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53248698; called by muse, mutect2, varscan2
- LRRC37B | c.1867T>G p.F623V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58951456; called by muse, mutect2
- MOGAT3 | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370137222; called by muse, mutect2, varscan2
- MS4A7 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55729184; called by muse, mutect2, varscan2
- MSI1 | c.345dup p.L116Afs*15 | Frame Shift Ins (INS) | VAF 18/173 reads (10%) | catalogued as rs748469666; called by mutect2, varscan2
- MUC17 | c.11241G>T p.M3747I | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as rs1200214531, COSV60283421; called by muse, mutect2, varscan2
- MYCBP2 | c.1670T>A p.L557H (on ENST00000357337; = p.L595H on NM_015057.5) | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62013173; called by muse, mutect2, varscan2
- NYX | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | catalogued as rs371622974, COSV61180452; called by muse, mutect2, varscan2
- OR4P4 | c.77T>C p.F26S | Missense Mutation (SNP) | VAF 105/358 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV58921141; called by muse, mutect2, varscan2
- PBRM1 | c.1677T>A p.Y559* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as COSV56267470; called by muse, mutect2, varscan2
- PBX2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1378437496, COSV66708762, COSV66708854; called by muse, mutect2, varscan2
- PCDHB14 | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as COSV53387363; called by muse, mutect2
- PCDHGA11 | c.1909G>C p.D637H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53915470, COSV53917862; called by muse, mutect2, varscan2
- PCLO | c.14948A>T p.Q4983L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV61623521; called by muse, mutect2, varscan2
- PCNX2 | c.2198A>G p.N733S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1483155236, COSV50787391; called by muse, mutect2, varscan2
- PEX5 | c.976T>G p.F326V (on ENST00000420616; = p.F318V on NM_000319.5) | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV56953805; called by muse, mutect2, varscan2
- PLA2G7 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51259125; called by muse, mutect2, varscan2
- PNPLA6 | c.821C>G p.T274S (on ENST00000414982 / NM_001166111.2; = p.T226S on NM_006702.5) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55375591; called by muse, mutect2
- RAB11FIP5 | c.1956dup p.K653Qfs*112 | Frame Shift Ins (INS) | VAF 22/187 reads (12%) | catalogued as rs755409958; called by mutect2, varscan2
- RNF180 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56960847; called by muse, mutect2, varscan2
- RORA | c.1447C>T p.R483* (on ENST00000335670 / NM_134261.3; = p.R508* on NM_002943.3) | Nonsense Mutation (SNP) | VAF 13/115 reads (11%) | catalogued as COSV55036874; called by muse, mutect2, varscan2
- SLC35G3 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as rs1192856920, COSV52010608; called by muse, mutect2, varscan2
- SMARCA1 | c.2147G>T p.R716I | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV64411276, COSV64412707; called by muse, mutect2
- SPAG16 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.805); catalogued as COSV55984130; called by muse, mutect2, varscan2
- SPTY2D1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 98/325 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as COSV60472646, COSV60473374; called by muse, mutect2, varscan2
- STPG2 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV54790305; called by muse, mutect2, varscan2
- TMEM145 | c.806+2T>C p.X269_splice | Splice Site (SNP) | VAF 79/249 reads (32%) | catalogued as COSV56624389; called by muse, mutect2, varscan2
- TNRC18 | c.5341G>T p.G1781C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101269467, COSV68163868; called by muse, mutect2, varscan2
- TNRC18 | c.5340G>T p.R1780S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV101269468, COSV68163875; called by muse, mutect2, varscan2
- VHL | c.575del p.P192Qfs*10 | Frame Shift Del (DEL) | VAF 38/79 reads (48%) | catalogued as COSV99078437; called by mutect2, pindel, varscan2
- VPS13C | c.4654G>A p.D1552N (on ENST00000644861 / NM_020821.3; = p.D1509N on NM_017684.5) | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51135025; called by muse, mutect2, varscan2
- ZDHHC2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.419); catalogued as COSV50497542; called by muse, mutect2, varscan2
- BCL3 | c.1299_1300del p.F434Cfs*32 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- CCNL1 | c.779del p.P260Rfs*24 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- CNTNAP3 | c.3752T>A p.I1251K | Missense Mutation (SNP) | VAF 26/495 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- EME1 | c.1555dup p.S519Ffs*3 | Frame Shift Ins (INS) | VAF 62/206 reads (30%) | called by mutect2, pindel, varscan2
- ENAM | c.428del p.S143Yfs*135 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- NBN | c.2184_2184+1del p.X728_splice | Splice Site (DEL) | VAF 51/156 reads (33%) | called by mutect2, pindel, varscan2
- NLRP8 | c.2768dup p.N923Kfs*2 | Frame Shift Ins (INS) | VAF 32/170 reads (19%) | called by mutect2, pindel, varscan2
- OR7D2 | c.578del p.F193Sfs*2 | Frame Shift Del (DEL) | VAF 73/556 reads (13%) | called by mutect2, pindel, varscan2
- SLC12A2 | c.3575_3580dup p.D1193_L1194insQD | In Frame Ins (INS) | VAF 74/327 reads (23%) | called by mutect2, pindel, varscan2
- TTC37 | c.1134+1del p.X378_splice | Splice Site (DEL) | VAF 51/204 reads (25%) | called by mutect2, pindel, varscan2
- ZNF277 | c.532del p.C178Afs*13 | Frame Shift Del (DEL) | VAF 34/222 reads (15%) | called by mutect2, pindel, varscan2
- ABCB11 | c.3279G>A p.S1093= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs368393726, COSV55585013; called by muse, mutect2
- ASH1L | c.294A>G p.K98= | Silent (SNP) | VAF 205/443 reads (46%) | catalogued as COSV64206493; called by muse, mutect2, varscan2
- CRACDL | c.471C>T p.D157= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs751150288, COSV67406610; called by muse, mutect2, varscan2
- FAM50B | c.339C>T p.R113= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV66654644; called by muse, mutect2
- IRS1 | c.585G>A p.V195= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV59334697; called by muse, mutect2, varscan2
- KIF15 | c.108T>C p.P36= | Silent (SNP) | VAF 61/169 reads (36%) | catalogued as COSV58159315; called by muse, mutect2, varscan2
- LAMA2 | c.7521T>C p.N2507= | Silent (SNP) | VAF 49/283 reads (17%) | catalogued as COSV70342717; called by muse, mutect2, varscan2
- NETO1 | c.1263G>A p.R421= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as COSV55003284; called by muse, mutect2, varscan2
- PISD | c.33A>G p.G11= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1569495064, COSV60672359; called by muse, mutect2, varscan2
- PRELP | c.627C>T p.D209= | Silent (SNP) | VAF 41/291 reads (14%) | catalogued as rs765943721, COSV58115353; called by muse, mutect2, varscan2
- RBM33 | c.480A>T p.I160= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV55296002; called by muse, mutect2, varscan2
- SAMD14 | c.192G>A p.S64= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV53309145, COSV99557404; called by muse, mutect2, varscan2
- SKA1 | c.138C>A p.I46= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV53278420; called by muse, mutect2, varscan2
- SPG11 | c.6783G>A p.L2261= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1239215346, COSV55992393; called by muse, mutect2, varscan2
- TBX3 | c.781T>C p.L261= (on ENST00000257566 / NM_016569.4; = p.L241= on NM_005996.4) | Silent (SNP) | VAF 70/479 reads (15%) | catalogued as COSV57470111; called by muse, mutect2, varscan2
- TRPC4 | c.814C>A p.R272= | Silent (SNP) | VAF 67/352 reads (19%) | catalogued as COSV58994311; called by muse, mutect2, varscan2
- TTC17 | c.2034A>G p.L678= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs993925618, COSV50006923; called by muse, mutect2, varscan2
- WDR35 | c.1203C>T p.N401= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as rs142103808; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TRAK1 | c.1963+85A>G | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
